Surgical pathology report (de-identified scan), TCGA case TCGA-4C-A93U, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-4C-A93U-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: F	Account: [REDACTED]
MRN: [REDACTED]	Date Collected: [REDACTED]
Requested by: [REDACTED]	Date Received: [REDACTED]
Patient: [REDACTED]	Date Reported: [REDACTED]

Clinical Data: Thyroid cancer

FINAL PATHOLOGIC DIAGNOSIS

- Right thyroid lobe (30 grams), thyroid lobectomy:
Papillary carcinoma of thyroid (6.5 cm), see *Synoptic Report*.
One benign perithyroid lymph node also present (0/1).

ICD-O-3
Carcinoma, papillary NOS
Date, Thyroid NOS
8050/3
673.9
3/26/14

SYNOPTIC REPORT

Tumor site:	Right lobe of thyroid
Histologic type:	Papillary carcinoma
Tumor size:	6.5 cm
Extrathyroidal extension:	Present, extensive
Surgical margins:	Tumor involves inked margin in anterior aspect of specimen
Angiolymphatic invasion:	Indeterminate
Perineural invasion:	Present
Lymph nodes:	One positive level IV lymph node identified (see separate specimens)
Surgical Pathology Staging:	pT4a N1b

- Right cricothyroid muscle: Negative for malignancy.
- Right inferior constrictor muscle: Negative for malignancy.
- Right anterior cricoid: Negative for malignancy.
- Tissue at right cricothyroid joint: Negative for malignancy.
- Right inferior parathyroid (40 mg): Benign normocellular parathyroid tissue identified.
- Right level IV lymph nodes: Negative for malignancy, two lymph nodes identified (0/2).
- Right level IV lymph nodes:
One of two lymph nodes are positive for metastatic papillary carcinoma (1/2).
Metastatic focus measures 0.4 cm, without extranodal extension.

[page 2 of 3]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

9. Right level IV lymph nodes #2: Negative for malignancy, nine lymph nodes identified (0/9).
10. Right level IIB lymph nodes: Negative for malignancy, two lymph nodes identified (0/2).
11. Right level IIA lymph nodes: Negative for malignancy, eleven lymph nodes identified (0/11).
12. Right level V lymph nodes: Negative for malignancy, twelve lymph nodes identified (0/12).
13. Right level III plum omohyoid muscle:
Negative for malignancy, three lymph nodes identified (0/3).
Portion of benign skeletal muscle also present.

Pathologist, Electronic Signature

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

1. **Right thyroid lobe:** In formalin labeled "right thyroid lobe" is a 30 gram, 6.5 x 3.5 x 2.6 cm thyroid lobe. The specimen is oriented with a single long stitch designated as superior, a double long stitch as inferior and the prevertebral fascia margin is inked blue by the surgeon. The capsular surface is red-purple and ragged. The specimen is inked as follows: anterior - green, posterior - blue and prevertebral fascia - black. Sectioning reveals a 6.5 cm in greatest dimension focally calcified, nodular tan-white mass extending from the superior pole to the inferior pole and which approaches the inked capsule and prevertebral fascia margin. The mass involves the majority of the thyroid parenchyma. Residual red-brown parenchyma is present at the periphery of the inferior pole. Representative sections are submitted sequentially from superior to inferior in 8 cassettes as A-H following decalcification.
2. **Right cricothyroid muscle:** Received fresh for frozen section as "right cricothyroid muscle" is a piece of pink-red soft tissue measuring up to 0.5 cm. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.
3. **Right inferior constrictor muscle:** Received fresh for frozen section as "right inferior constrictor muscle" is a piece of pink-tan soft tissue measuring up to 0.3 cm. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.
4. **Right anterior cricoid:** Received fresh for frozen section as "right anterior cricoid" is a piece of pink-red soft tissue measuring up to 0.4 cm. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.
5. **Tissue at right cricothyroid joint:** Received fresh for frozen section as "tissue at right cricothyroid joint" is a piece of tan soft tissue measuring up to 0.3 cm. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.
6. **Right inferior parathyroid:** Received fresh for frozen section as "right inferior parathyroid" is a piece of pink-tan soft tissue measuring up to 0.6 cm and weighing 40 mg. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.
7. **Right level IV lymph node:** In formalin labeled "right level IV lymph node" is a 3.5 x 2.8 x 1.5 cm aggregate of adipose tissue. Sectioning reveals 2 lymph nodes 0.9 and 1.3 cm in greatest dimension. The nodes are differentially inked, bisected and both entirely submitted in one cassette.
8. **Right level IV lymph node:** Received fresh for frozen section as "right level IV lymph node" are four pieces of apparent pink-brown lymph nodes, ranging in size from 0.4 cm to 1.4 cm in greatest dimension. The specimen is entirely submitted for frozen section evaluation. The frozen section remnant is submitted for permanent sections in one cassette.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

9. **Right level IV lymph node #2:** In formalin labeled "right level IV lymph node" is a 4.5 x 3.5 x 1.5 cm aggregate of fibrofatty tissue. Sectioning reveals multiple nodes ranging to 1.1 cm in greatest dimension which are submitted in two cassettes as labeled: A five nodes; B four nodes.
10. **Right level IIB:** In formalin labeled "right level IIB" is a 2.6 x 1.8 x 1.5 cm aggregate of adipose tissue. Sectioning reveals two lymph nodes which are submitted in one cassette.
11. **Right level IIA:** In formalin labeled "right level IIA" is a 5 x 3.2 x 1.8 cm portion of adipose tissue. Sectioning reveals multiple lymph nodes ranging to 1.8 cm in greatest dimension which are submitted in three cassettes as labeled: A six nodes; B four nodes; C largest node, bisected.
12. **Right level V:** In formalin labeled "right level V" is a 6.5 x 4.8 x 2.2 cm portion of fibrofatty tissue. Sectioning reveals multiple lymph nodes which are submitted in three cassettes as labeled: A four nodes; B five nodes; C five nodes.
13. **Right level III plus omohyoid muscle:** In formalin labeled "right level III plus omohyoid muscle" is a 5 x 4.5 x 2.2 cm aggregate of fibrofatty tissue and muscle. Sectioning reveals two definitive lymph nodes. No gross tumor is identified in the portion of muscle. Representative sections are submitted in two cassettes as labeled: A two lymph nodes; B representative muscle.

INTRAOPERATIVE REPORT:

2. Frozen Section Diagnosis: **Negative for malignancy.**
[interpreted by
3. Frozen Section Diagnosis: **Negative for malignancy.**
[interpreted by
4. Frozen Section Diagnosis: **Negative for malignancy.**
[interpreted by
5. Frozen Section Diagnosis: **Negative for malignancy.**
[interpreted by
6. Frozen Section Diagnosis: **Benign parathyroid tissue identified.**
[interpreted by
8. Frozen Section Diagnosis: **Positive for metastatic papillary carcinoma.**
[interpreted by

CPT CODE(S):

88331 x6, 88307 x8, 88305 x7

ICD-9 CODE(S):

[193]

FACILITY:

END OF REPORT

Criteria	lw 12/13/13	Yes	No

Source: NCI Genomic Data Commons file 1a2e7442-442f-423c-a92e-9aeefc60f1ee (TCGA-4C-A93U.52F5D12B-92C9-4A98-A9EB-42BF48C0BA87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).